Somatic mutation profile of tumor specimen 0DU07S from CCDI case PBCKAG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.0 years (2,569 days).
Specimen 0DU07S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b270dbf-b9b3-4c45-bfff-227ab1353236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a644fc0-f1f7-4783-b3f3-ddc8e3ab188c

The open-access MAF lists 87 somatic variants for this specimen: 49 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 21, Intron 8, Nonsense Mutation 7, 3'UTR 5, 5'UTR 3, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 6445/7219 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571806, COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- CFAP47 | c.7727A>T p.D2576V | Missense Mutation (SNP) | VAF 622/1649 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.526); catalogued as rs781844758; called by muse, mutect2, varscan2
- EXD2 | c.1555C>T p.R519* (on ENST00000312994 / NM_001193362.1; = p.R394* on NM_018199.3) | Nonsense Mutation (SNP) | VAF 667/1379 reads (48%) | catalogued as rs768692297; called by muse, mutect2, varscan2
- FAT1 | c.6745G>A p.A2249T | Missense Mutation (SNP) | VAF 604/1430 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV71673750; called by muse, mutect2, varscan2
- GPT | c.306C>G p.D102E | Missense Mutation (SNP) | VAF 526/2411 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200388860; called by muse, mutect2, varscan2
- GSTM5 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 663/1648 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1158434732, COSV56660261; called by muse, mutect2, varscan2
- KIAA1109 | c.9748C>T p.R3250* | Nonsense Mutation (SNP) | VAF 385/925 reads (42%) | catalogued as rs1327756247, COSV99145335; called by muse, mutect2, varscan2
- KMT2C | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 180/900 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51472122; called by muse, varscan2
- LRP1 | c.10920C>A p.D3640E | Missense Mutation (SNP) | VAF 464/2009 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99675017; called by muse, mutect2, varscan2
- MAP3K11 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 946/2094 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs145124492; called by mutect2, varscan2
- NUP210 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 1340/2525 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs778461341, COSV54408919; called by muse, mutect2, varscan2
- OR4C13 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 100/2160 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV73648730; called by muse, mutect2
- PTPRS | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 333/782 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV53609338; called by muse, mutect2, varscan2
- SLC9A9 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 871/1843 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57247252; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 634/1044 reads (61%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TRPC7 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 405/1392 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1209602545, COSV61453423, COSV61457143; called by muse, mutect2, varscan2
- ZNF879 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 399/1536 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as COSV71424537; called by muse, mutect2, varscan2
- AFG3L2 | c.753C>A p.G251= | Splice Region (SNP) | VAF 174/382 reads (46%) | called by muse, mutect2, varscan2
- AFTPH | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 695/2368 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD61 | c.858C>A p.C286* | Nonsense Mutation (SNP) | VAF 393/1456 reads (27%) | called by muse, mutect2, varscan2
- COA1 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 637/2454 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.4204A>T p.T1402S (on ENST00000520002; = p.T1401S on NM_033225.6) | Missense Mutation (SNP) | VAF 772/3026 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CTPS2 | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 241/554 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DCBLD2 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 64/2346 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); called by muse, mutect2
- DOCK5 | c.1150A>G p.N384D | Missense Mutation (SNP) | VAF 471/2039 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- EPHB2 | c.598A>C p.I200L | Missense Mutation (SNP) | VAF 80/1666 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, mutect2
- GAPVD1 | c.2367C>A p.C789* | Nonsense Mutation (SNP) | VAF 325/850 reads (38%) | called by muse, mutect2, varscan2
- HDAC6 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 257/889 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LGALS3BP | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 328/1537 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAPRE3 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 186/2632 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- MGAM | c.5224G>T p.D1742Y | Missense Mutation (SNP) | VAF 171/3230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- NBEAL1 | c.2176C>G p.Q726E | Missense Mutation (SNP) | VAF 123/2848 reads (4%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NRK | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 332/1138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ONECUT2 | c.1047C>A p.Y349* | Nonsense Mutation (SNP) | VAF 80/1264 reads (6%) | called by muse, mutect2
- ORC4 | c.1064A>G p.K355R | Missense Mutation (SNP) | VAF 786/2484 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- P2RY12 | c.342C>A p.F114L | Missense Mutation (SNP) | VAF 726/2031 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PLRG1 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 413/952 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PZP | c.3991C>A p.Q1331K | Missense Mutation (SNP) | VAF 363/1490 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RAB9B | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 542/1586 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC25A14 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 490/1298 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SLC2A3 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 468/1877 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC4A10 | c.2137C>G p.R713G (on ENST00000446997 / NM_001354461.2; = p.R683G on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 300/1045 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- STAU2 | c.632T>C p.L211S (on ENST00000524300 / NM_001164380.2; = p.L179S on NM_014393.2) | Missense Mutation (SNP) | VAF 119/2848 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2
- TEX11 | c.1795A>C p.K599Q (on ENST00000344304; = p.K584Q on NM_031276.3) | Missense Mutation (SNP) | VAF 473/1299 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TNPO1 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 409/1269 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49B | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 782/3982 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRIM49D1 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 613/2712 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49D2 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 226/929 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- ZSWIM1 | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 569/1900 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- AC109583.1 | c.960C>A p.G320= | Silent (SNP) | VAF 600/1179 reads (51%) | called by muse, mutect2, varscan2
- BBS9 | c.1419C>A p.T473= | Silent (SNP) | VAF 637/2213 reads (29%) | called by muse, mutect2, varscan2
- BTN3A3 | c.1008C>A p.L336= | Silent (SNP) | VAF 82/1150 reads (7%) | called by muse, mutect2
- CCNO | c.429G>T p.V143= | Silent (SNP) | VAF 229/1406 reads (16%) | called by muse, mutect2, varscan2
- CHST8 | c.798C>T p.S266= | Silent (SNP) | VAF 582/1364 reads (43%) | catalogued as rs201170575; called by muse, mutect2, varscan2
- DNMBP | c.417G>A p.L139= | Silent (SNP) | VAF 72/925 reads (8%) | called by muse, mutect2
- DNMT3A | c.1458G>A p.K486= | Silent (SNP) | VAF 120/2526 reads (5%) | catalogued as rs1373978724; called by muse, mutect2
- EGFLAM | c.1980C>T p.D660= | Silent (SNP) | VAF 533/1990 reads (27%) | called by muse, mutect2, varscan2
- HERC2 | c.11187C>G p.S3729= | Silent (SNP) | VAF 535/1307 reads (41%) | catalogued as COSV55350977; called by muse, mutect2, varscan2
- KIAA1109 | c.12990C>G p.T4330= | Silent (SNP) | VAF 478/1039 reads (46%) | called by muse, mutect2, varscan2
- KIF4B | c.2130C>G p.A710= | Silent (SNP) | VAF 1061/2564 reads (41%) | called by muse, mutect2, varscan2
- KSR2 | c.555G>A p.P185= | Silent (SNP) | VAF 373/2294 reads (16%) | catalogued as rs373628463; called by muse, mutect2, varscan2
- NEB | c.7102C>T p.L2368= | Silent (SNP) | VAF 592/1980 reads (30%) | called by muse, mutect2, varscan2
- NEK1 | c.402A>T p.I134= | Silent (SNP) | VAF 371/847 reads (44%) | called by muse, mutect2, varscan2
- NFASC | c.582C>T p.N194= (on ENST00000339876 / NM_001378329.1; = p.N188= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 705/1696 reads (42%) | catalogued as rs368438179; called by muse, mutect2, varscan2
- PATE1 | c.180C>T p.C60= | Silent (SNP) | VAF 1518/3380 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.1680G>A p.P560= | Silent (SNP) | VAF 132/2432 reads (5%) | catalogued as COSV53975661; called by muse, mutect2
- SLC38A8 | c.849C>T p.D283= | Silent (SNP) | VAF 486/1292 reads (38%) | catalogued as rs749686942, COSV55309491; ClinVar: likely benign; called by muse, mutect2, varscan2
- UPF2 | c.15T>C p.R5= | Silent (SNP) | VAF 136/1581 reads (9%) | called by muse, mutect2
- UTP14A | c.2295G>T p.L765= | Silent (SNP) | VAF 76/1340 reads (6%) | catalogued as COSV100928961; called by muse, mutect2
- XIRP2 | c.4320A>G p.K1440= (on ENST00000628543; = p.K1615= on NM_152381.6) | Silent (SNP) | VAF 589/2370 reads (25%) | called by muse, mutect2, varscan2
- ASPHD1 | c.*87C>T | 3'UTR (SNP) | VAF 42/106 reads (40%) | catalogued as rs1033338303; called by muse, mutect2
- CCS | c.429-33C>A | Intron (SNP) | VAF 106/663 reads (16%) | called by muse, mutect2, varscan2
- CDC25C | c.*21G>T | 3'UTR (SNP) | VAF 132/740 reads (18%) | called by muse, mutect2, varscan2
- EFHD1 | c.*49G>T | 3'UTR (SNP) | VAF 102/363 reads (28%) | called by muse, mutect2, varscan2
- EVI5L | c.-31A>G | 5'UTR (SNP) | VAF 394/957 reads (41%) | catalogued as rs1025030464; called by muse, mutect2, varscan2
- FCRL1 | c.52+100G>T | Intron (SNP) | VAF 13/396 reads (3%) | called by muse, mutect2
- FTSJ1 | c.122-50T>A | Intron (SNP) | VAF 120/304 reads (39%) | called by muse, mutect2, varscan2
- IL5RA | c.994+2046C>A | Intron (SNP) | VAF 313/682 reads (46%) | called by muse, mutect2, varscan2
- MAP3K19 | c.22+1045G>T | Intron (SNP) | VAF 38/1090 reads (3%) | called by muse, mutect2
- MUC19 | n.19412T>G | RNA (SNP) | VAF 187/1579 reads (12%) | called by muse, mutect2, varscan2
- OR2A7 | c.-24C>T | 5'UTR (SNP) | VAF 119/691 reads (17%) | called by muse, mutect2, varscan2
- SIRT6 | c.*21G>T | 3'UTR (SNP) | VAF 183/455 reads (40%) | called by muse, mutect2, varscan2
- SNX1 | c.1016-21G>T | Intron (SNP) | VAF 165/374 reads (44%) | called by muse, mutect2, varscan2
- TBX10 | c.-21C>T | 5'UTR (SNP) | VAF 212/1017 reads (21%) | called by muse, mutect2, varscan2
- TMA16 | c.117-96A>T | Intron (SNP) | VAF 76/174 reads (44%) | called by muse, mutect2, varscan2
- VPS52 | c.991+62G>T | Intron (SNP) | VAF 162/374 reads (43%) | called by muse, mutect2, varscan2
- WDFY1 | c.*100C>G | 3'UTR (SNP) | VAF 46/208 reads (22%) | called by muse, mutect2, varscan2
